Somatic mutation profile of tumor specimen ALCH-B28N-TTP1-A (aliquot ALCH-B28N-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B28N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,194 days).
Specimen ALCH-B28N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2aaf27a-d552-4979-967d-223db67dd568.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28N-NB1-A (Blood Derived Normal), aliquot ALCH-B28N-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7c55751-00d7-486b-86d7-b7260bc1a9e4

The open-access MAF lists 350 somatic variants for this specimen: 233 protein-altering or splice-affecting, 71 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 71, Intron 18, Nonsense Mutation 18, 3'UTR 8, 5'UTR 8, Splice Site 7, RNA 6, 5'Flank 5, Frame Shift Del 5, Splice Region 4, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.64A>C p.K22Q | Missense Mutation (SNP) | VAF 93/585 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555201381, COSV56983663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 169/551 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 23/140 reads (16%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2008C>A p.L670I | Missense Mutation (SNP) | VAF 49/457 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV60632878; called by muse, mutect2, varscan2
- ADAM33 | c.735C>A p.D245E | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs752230445; called by muse, mutect2, varscan2
- ADAMTS20 | c.4832G>T p.R1611M | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101240554, COSV67133016; called by muse, mutect2, varscan2
- AR | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV65964845; called by muse, mutect2, varscan2
- ATM | c.1152C>A p.C384* | Nonsense Mutation (SNP) | VAF 40/401 reads (10%) | catalogued as COSV99589592; called by muse, varscan2
- B4GALNT4 | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1403986530; called by muse, mutect2, varscan2
- BAG4 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs760711712; called by muse, mutect2, varscan2
- C10orf67 | c.976-1G>C p.X326_splice | Splice Site (SNP) | VAF 18/172 reads (10%) | catalogued as rs935900051; called by muse, mutect2, varscan2
- C1QL2 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1301981755; called by muse, mutect2, varscan2
- C4orf54 | c.2857G>T p.E953* | Nonsense Mutation (SNP) | VAF 38/227 reads (17%) | catalogued as COSV72766762; called by muse, mutect2, varscan2
- CCDC158 | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66355226; called by muse, mutect2, varscan2
- CDH8 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 79/667 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV54866428, COSV54887800; called by muse, mutect2, varscan2
- CEP41 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 76/519 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1236914615, COSV56220540; called by muse, mutect2, varscan2
- CERS3 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52572106; called by muse, mutect2
- CNTNAP2 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 47/432 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62216781; called by muse, mutect2, varscan2
- CNTNAP4 | c.2366G>T p.R789I | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1462368941, COSV56679526; called by muse, mutect2
- COL11A1 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 75/664 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs748315186, COSV100615029; called by muse, mutect2, varscan2
- CSMD3 | c.9079C>A p.L3027I (on ENST00000297405 / NM_001363185.1; = p.L2858I on NM_052900.3) | Missense Mutation (SNP) | VAF 94/728 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52272316; called by muse, mutect2, varscan2
- CSMD3 | c.4991C>A p.P1664Q (on ENST00000297405 / NM_001363185.1; = p.P1560Q on NM_052900.3) | Missense Mutation (SNP) | VAF 47/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52258540; called by muse, mutect2, varscan2
- DROSHA | c.2789G>T p.R930I | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV60776988; called by muse, mutect2, varscan2
- ERN2 | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs900407796; called by muse, mutect2, varscan2
- FAM214A | c.2969G>T p.R990L | Missense Mutation (SNP) | VAF 30/469 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55924796; called by muse, mutect2
- GPR32 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1568459656; called by muse, mutect2
- HIVEP1 | c.6010A>G p.I2004V | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs776292825, COSV101045766; called by muse, mutect2, varscan2
- KCNV1 | c.1288C>A p.R430S | Missense Mutation (SNP) | VAF 56/577 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV52086119; called by muse, mutect2
- KHDRBS2 | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55495046, COSV99838541; called by muse, mutect2, varscan2
- KIT | c.2322C>A p.Y774* | Nonsense Mutation (SNP) | VAF 66/702 reads (9%) | catalogued as COSV55387404; called by muse, mutect2
- KRTAP10-10 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 60/492 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59960085; called by mutect2, varscan2
- KRTAP10-5 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 54/598 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs587669303, COSV100553454, COSV59953294; called by muse, mutect2
- LAMB4 | c.675C>A p.N225K | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223475; called by muse, mutect2
- LRP1B | c.2662G>T p.D888Y | Missense Mutation (SNP) | VAF 41/377 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV63341658, COSV63342038; called by muse, mutect2, varscan2
- LRRTM4 | c.1096G>T p.V366F | Missense Mutation (SNP) | VAF 60/418 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as COSV69139878; called by muse, mutect2, varscan2
- MROH2B | c.4740G>C p.E1580D | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs1374087083; called by muse, mutect2
- MUC16 | c.18770C>A p.P6257H | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.184); catalogued as COSV101201445; called by muse, mutect2, varscan2
- NCAPG2 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780591786, COSV51991840, COSV99317151; called by muse, mutect2, varscan2
- NCOA4 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 37/366 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs782465567; called by muse, mutect2
- NOS1 | c.3214G>T p.E1072* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as COSV57609281; called by muse, mutect2
- NUPR2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1218858687, COSV61409452; called by mutect2, varscan2
- OR51I1 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 71/565 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs772637819, COSV66507838; called by muse, mutect2, varscan2
- OR5D18 | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs143615376, COSV100450494, COSV100450859; called by muse, mutect2, varscan2
- OR5R1 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 66/449 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV56571530; called by muse, mutect2, varscan2
- OSBPL8 | c.2034G>T p.Q678H | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675571; called by muse, mutect2, varscan2
- OSBPL8 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 90/454 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV53881722; called by muse, mutect2, varscan2
- OTOA | c.2017C>T p.H673Y (on ENST00000286149; = p.H659Y on NM_144672.4) | Missense Mutation (SNP) | VAF 62/608 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs766019997, COSV53764130; called by muse, mutect2, varscan2
- OTOG | c.7177C>A p.Q2393K | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs988460880; called by muse, mutect2, varscan2
- PCDHGB1 | c.711del p.V238Cfs*24 | Frame Shift Del (DEL) | VAF 40/304 reads (13%) | catalogued as COSV53944722, COSV54028858; called by mutect2, pindel, varscan2
- PER3 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 68/531 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV100728459; called by muse, mutect2, varscan2
- PLG | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 61/471 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV51983784; called by muse, mutect2, varscan2
- PRDM9 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 99/787 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs200386479, COSV57006661; called by muse, mutect2, varscan2
- RP1 | c.354C>A p.D118E | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55118684; called by muse, mutect2
- RPTN | c.989A>G p.H330R | Missense Mutation (SNP) | VAF 90/918 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV60168848; called by muse, mutect2
- RTP5 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541685876; called by muse, mutect2, varscan2
- SEC23B | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 84/647 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750888081, CM094616, COSV52719374; called by muse, mutect2, varscan2
- SEMA3D | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 20/771 reads (3%) | SIFT tolerated (1); PolyPhen possibly damaging (0.555); catalogued as COSV99407456; called by muse, mutect2
- SEZ6L | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs774698528, COSV50677243; called by muse, mutect2, varscan2
- SGCD | c.568C>G p.L190V (on ENST00000435422 / NM_001128209.2; = p.L191V on NM_000337.5) | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100551179; called by muse, mutect2
- SGCZ | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 55/425 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV66041799, COSV66054267; called by muse, mutect2, varscan2
- SLC45A2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 64/622 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554113064, COSV56874201; called by muse, mutect2
- SNCA | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 49/566 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1219278381, COSV100410059; called by muse, mutect2
- SP140L | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 35/210 reads (17%) | catalogued as COSV54742079; called by muse, mutect2, varscan2
- SPATC1 | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.381); catalogued as COSV101084818; called by muse, mutect2, varscan2
- SPRED1 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 32/844 reads (4%) | catalogued as COSV54440112; called by muse, mutect2
- ST6GAL2 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | PolyPhen possibly damaging (0.863); catalogued as rs1021383351, COSV64532064; called by muse, mutect2, varscan2
- TAAR6 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 84/767 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1234419077, COSV51583411; called by muse, mutect2, varscan2
- TBC1D22B | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs1295747718; called by muse, mutect2, varscan2
- TET2 | c.2421G>T p.E807D | Missense Mutation (SNP) | VAF 62/734 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV54439116; called by muse, mutect2
- TET2 | c.3647G>T p.R1216L | Missense Mutation (SNP) | VAF 54/676 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54424941; called by muse, mutect2
- TEX35 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.059); catalogued as COSV51103128; called by muse, mutect2, varscan2
- TNRC6C | c.1904G>A p.R635K | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1224802722; called by muse, mutect2, varscan2
- TRBV29-1 | c.34+1G>C p.X12_splice | Splice Site (SNP) | VAF 64/419 reads (15%) | catalogued as rs545473233; called by muse, mutect2, varscan2
- TRIM29 | c.1082del p.K361Sfs*23 | Frame Shift Del (DEL) | VAF 37/258 reads (14%) | catalogued as COSV59279797; called by mutect2, pindel, varscan2
- TRIM49B | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 107/671 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs1426808373; called by muse, mutect2, varscan2
- TRPS1 | c.3022G>T p.G1008C (on ENST00000220888 / NM_001330599.2; = p.G1021C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as COSV55255399; called by muse, mutect2, varscan2
- TSEN2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV53188694; called by muse, mutect2, varscan2
- TUBB1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 68/616 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as rs749343000, COSV53886436; called by muse, mutect2, varscan2
- UBE2J2 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs928340026, COSV59572156; called by muse, mutect2, varscan2
- UBE2J2 | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV59573729, COSV59574244; called by muse, mutect2, varscan2
- USP3 | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99165623; called by muse, mutect2
- VAT1L | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 24/313 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as COSV56815881; called by muse, mutect2
- WLS | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV99260267; called by muse, mutect2, varscan2
- ZNF713 | c.93G>C p.E31D (on ENST00000633730 / NM_001366796.2; = p.E44D on NM_182633.3) | Missense Mutation (SNP) | VAF 49/352 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV68887997; called by muse, mutect2, varscan2
- ZNF90 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.189); catalogued as COSV69004078; called by muse, mutect2
- ZSCAN12 | c.665G>T p.R222M | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs369910447; called by muse, mutect2, varscan2
- ABCA7 | c.4984G>T p.G1662* | Nonsense Mutation (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- ACR | c.712-8del | Splice Region (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- ADAM33 | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ADAR | c.2457G>T p.M819I | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.039); called by muse, varscan2
- ADAR | c.1981A>T p.S661C | Missense Mutation (SNP) | VAF 165/685 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGBL1 | c.2096C>A p.T699K | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ALDH8A1 | c.1101C>A p.N367K | Missense Mutation (SNP) | VAF 62/389 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ALG2 | c.842A>T p.Y281F | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ALMS1 | c.3527G>T p.G1176V | Missense Mutation (SNP) | VAF 51/430 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ANK1 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 72/538 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKFN1 | c.2105G>A p.R702K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- ARHGEF33 | c.1214A>G p.H405R | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ARID2 | c.3122A>G p.Q1041R | Missense Mutation (SNP) | VAF 60/342 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ATP10D | c.3215G>T p.G1072V | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- AURKC | c.302C>G p.P101R (on ENST00000302804 / NM_001015878.2; = p.P67R on NM_003160.3) | Missense Mutation (SNP) | VAF 46/554 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.333); called by muse, mutect2
- AVPR1A | c.1163A>C p.Y388S | Missense Mutation (SNP) | VAF 70/441 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- C3orf85 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CCDC42 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CDH26 | c.2370T>A p.C790* (on ENST00000348616 / NM_177980.4; = p.C123* on NM_021810.6) | Nonsense Mutation (SNP) | VAF 54/397 reads (14%) | called by muse, mutect2, varscan2
- CEP89 | c.1362C>G p.S454R | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CHCHD3 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CHST3 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTLA4 | c.108A>T p.K36N | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP2F1 | c.1152+1G>A p.X384_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | called by muse, varscan2
- DARS2 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF12L1 | c.829C>A p.L277M | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCHS1 | c.6758G>T p.G2253V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDO | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DHX16 | c.989A>T p.E330V | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- DMWD | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- DNAI3 | c.1553G>T p.C518F | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DOCK2 | c.1668C>A p.S556R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- EEF1A2 | c.1219G>T p.G407* | Nonsense Mutation (SNP) | VAF 36/217 reads (17%) | called by muse, mutect2, varscan2
- EMB | c.928A>C p.N310H | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EPHA5 | c.1506T>A p.Y502* | Nonsense Mutation (SNP) | VAF 34/229 reads (15%) | called by muse, mutect2, varscan2
- EPPK1 | c.42del p.N15Tfs*29 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- FBLN2 | c.164G>C p.C55S | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBLN2 | c.3204C>A p.C1068* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | called by muse, varscan2
- FCRL5 | c.1625C>G p.T542R | Missense Mutation (SNP) | VAF 97/469 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FRMD1 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FSIP2 | c.9128T>G p.L3043* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- GABRA1 | c.187+1G>C p.X63_splice | Splice Site (SNP) | VAF 45/472 reads (10%) | called by muse, mutect2
- GJC3 | c.748G>T p.V250L | Missense Mutation (SNP) | VAF 67/516 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GP6 | c.483C>A p.Y161* | Nonsense Mutation (SNP) | VAF 39/351 reads (11%) | called by muse, mutect2, varscan2
- GRB7 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- GRIN3A | c.2352+2T>C p.X784_splice | Splice Site (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2, varscan2
- GRM6 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- HEMGN | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HMCN1 | c.2378C>A p.P793Q | Missense Mutation (SNP) | VAF 35/407 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HNRNPF | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); called by muse, mutect2
- HSPA13 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 28/664 reads (4%) | called by muse, mutect2
- HTR4 | c.936C>A p.Y312* | Nonsense Mutation (SNP) | VAF 51/466 reads (11%) | called by muse, mutect2, varscan2
- ICE2 | c.101A>G p.H34R | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IKBKE | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- IL9R | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 53/412 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IPO11 | c.2556G>T p.L852F | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- JAK3 | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, varscan2
- KARS1 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 66/586 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- KCNC2 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 93/645 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- KCNH7 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCNQ5 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- KIAA2012 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIF27 | c.2667G>T p.Q889H | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- KIF27 | c.2666A>T p.Q889L | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL35 | c.426C>A p.C142* | Nonsense Mutation (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- L2HGDH | c.1207G>T p.G403* | Nonsense Mutation (SNP) | VAF 38/424 reads (9%) | called by muse, mutect2
- LCOR | c.3453C>A p.S1151R | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LILRA4 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LILRA4 | c.530A>T p.Q177L | Missense Mutation (SNP) | VAF 47/390 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LMX1B | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.54); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LRRC4C | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 59/414 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- LRRC7 | c.3499A>G p.R1167G (on ENST00000651989 / NM_001370785.2; = p.R1134G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/409 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- MCF2L2 | c.1675+1G>T p.X559_splice | Splice Site (SNP) | VAF 15/82 reads (18%) | called by muse, varscan2
- MRC1 | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 86/679 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MRC1 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 62/682 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2
- MYH2 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 63/554 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NAV3 | c.2081A>C p.Q694P | Missense Mutation (SNP) | VAF 78/458 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NOTCH4 | c.4237G>T p.A1413S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NRXN2 | c.743T>C p.M248T | Missense Mutation (SNP) | VAF 74/506 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, varscan2
- OR10T2 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- OR52K2 | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- OR5B12 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 61/603 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- OR5I1 | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR7A10 | c.927dup p.*310Ifs*11 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | called by mutect2, pindel
- OSBPL10 | c.868G>T p.G290W | Missense Mutation (SNP) | VAF 113/640 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OVCH1 | c.3118C>G p.R1040G | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- P3H1 | c.815A>T p.Y272F | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2
- PANX3 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 68/540 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.541); called by muse, varscan2
- PCDHA2 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 56/659 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA7 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 46/395 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PCDHGA3 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- PLCB1 | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2
- PLCE1 | c.1933A>T p.M645L | Missense Mutation (SNP) | VAF 64/595 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- POLR1F | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PPM1B | c.745A>T p.M249L | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PRKDC | c.9160C>T p.Q3054* | Nonsense Mutation (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- PRSS41 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN4 | c.2315G>A p.G772D | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PTPRB | c.2973del p.R992Gfs*10 | Frame Shift Del (DEL) | VAF 35/246 reads (14%) | called by mutect2, pindel, varscan2
- PTPRQ | c.1790G>A p.G597E (on ENST00000616559; = p.G555E on NM_001145026.2) | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB3C | c.47G>T p.R16M | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RASGRP3 | c.1232A>C p.K411T (on ENST00000402538 / NM_001349975.2; = p.K410T on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/377 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- RBFOX1 | c.458G>T p.R153I (on ENST00000641259; = p.R37I on NM_001308117.1) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- RP1 | c.4951A>C p.T1651P | Missense Mutation (SNP) | VAF 131/863 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTL4 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RTP5 | c.1663T>A p.F555I | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- SAMSN1 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 27/442 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- SCN1A | c.2922G>T p.M974I (on ENST00000303395 / NM_001202435.3; = p.M963I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/608 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- SIRT4 | c.416G>T p.W139L | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); called by muse, mutect2
- SLC28A3 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SLC5A11 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLC6A13 | c.479-5G>T | Splice Region (SNP) | VAF 30/206 reads (15%) | called by mutect2, varscan2
- SMARCA1 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STRC | c.3928C>A p.L1310M | Missense Mutation (SNP) | VAF 18/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- STYXL2 | c.1812C>A p.N604K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- SULT1A1 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBC1D1 | c.2071C>A p.L691I | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TEP1 | c.6917T>C p.L2306S | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THSD4 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.01); called by muse, mutect2
- TMEM117 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 95/439 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TMEM254 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 59/423 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM86A | c.28A>T p.S10C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TMEM9 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 26/329 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- TMTC3 | c.620A>T p.Q207L | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2
- TNFSF18 | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- TNR | c.3629T>A p.L1210Q | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV2 | c.132del p.I45Sfs*52 | Frame Shift Del (DEL) | VAF 44/338 reads (13%) | called by mutect2, pindel, varscan2
- TRIML2 | c.912C>G p.H304Q | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRPA1 | c.1529+5G>A | Splice Region (SNP) | VAF 36/317 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.3433A>T p.M1145L (on ENST00000591111; = p.M1099L on NM_003319.4) | Missense Mutation (SNP) | VAF 101/636 reads (16%) | PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TXLNB | c.1801C>A p.Q601K | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.018); called by muse, mutect2
- TXLNB | c.304T>A p.C102S | Missense Mutation (SNP) | VAF 82/624 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR5 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- VPS35 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 32/381 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2
- VSIG10L | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- VWF | c.2188T>C p.Y730H | Missense Mutation (SNP) | VAF 57/445 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- WARS2 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 57/350 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY3 | c.4856A>T p.E1619V | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR35 | c.1288+1dup p.X430_splice (on ENST00000345530 / NM_001006657.2; = p.X419_splice on NM_020779.4) | Splice Site (INS) | VAF 37/228 reads (16%) | called by mutect2, pindel, varscan2
- WEE2 | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 45/400 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- XKR5 | c.873G>T p.W291C | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- XPO1 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 8/239 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- ZEB1 | c.329A>T p.D110V | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF283 | c.1382G>A p.C461Y | Missense Mutation (SNP) | VAF 48/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF536 | c.1770C>G p.S590R | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF737 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 42/498 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); called by muse, mutect2
- ZPBP | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 31/331 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- ADAMTS2 | c.438C>G p.T146= | Silent (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- ALPK1 | c.2604G>T p.G868= | Silent (SNP) | VAF 30/316 reads (9%) | called by muse, mutect2
- ALPK1 | c.2886G>T p.P962= | Silent (SNP) | VAF 43/425 reads (10%) | called by muse, mutect2
- ARSB | c.894T>C p.S298= | Silent (SNP) | VAF 42/418 reads (10%) | called by muse, mutect2
- ASCC3 | c.5289T>A p.L1763= | Silent (SNP) | VAF 26/248 reads (10%) | called by muse, varscan2
- BIRC6 | c.6588G>A p.L2196= | Silent (SNP) | VAF 41/282 reads (15%) | called by muse, mutect2, varscan2
- BMX | c.1062T>C p.N354= | Silent (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- BTBD11 | c.2457C>A p.V819= (on ENST00000280758 / NM_001018072.2; = p.V356= on NM_001017523.2) | Silent (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2
- CD248 | c.303C>A p.R101= | Silent (SNP) | VAF 34/220 reads (15%) | called by muse, mutect2, varscan2
- CFAP46 | c.6543T>A p.R2181= | Silent (SNP) | VAF 23/148 reads (16%) | called by muse, mutect2, varscan2
- CFAP54 | c.5793A>T p.A1931= | Silent (SNP) | VAF 47/278 reads (17%) | called by muse, mutect2, varscan2
- CHAT | c.1894C>A p.R632= | Silent (SNP) | VAF 85/735 reads (12%) | called by muse, mutect2, varscan2
- COL9A1 | c.717G>T p.L239= | Silent (SNP) | VAF 90/787 reads (11%) | called by muse, mutect2, varscan2
- CRAT | c.1704C>T p.P568= | Silent (SNP) | VAF 32/197 reads (16%) | catalogued as rs145730542; called by muse, mutect2, varscan2
- CXCR1 | c.267C>A p.A89= | Silent (SNP) | VAF 54/381 reads (14%) | called by muse, mutect2, varscan2
- DCSTAMP | c.510C>G p.T170= | Silent (SNP) | VAF 42/312 reads (13%) | catalogued as COSV52577620; called by muse, mutect2, varscan2
- DISP3 | c.3588C>A p.A1196= | Silent (SNP) | VAF 31/232 reads (13%) | called by muse, mutect2, varscan2
- DMBT1 | c.561C>A p.L187= | Silent (SNP) | VAF 38/294 reads (13%) | called by muse, mutect2, varscan2
- DNAH5 | c.3585T>C p.I1195= | Silent (SNP) | VAF 20/243 reads (8%) | catalogued as rs1377571750; called by muse, mutect2
- EEF1A2 | c.1218G>T p.P406= | Silent (SNP) | VAF 39/224 reads (17%) | catalogued as COSV53204952, COSV99419206; called by muse, mutect2, varscan2
- ETV3L | c.531G>A p.Q177= | Silent (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2
- FIGN | c.2127A>T p.P709= | Silent (SNP) | VAF 59/492 reads (12%) | called by muse, mutect2, varscan2
- FJX1 | c.219C>T p.R73= | Silent (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- FRS2 | c.288A>G p.E96= | Silent (SNP) | VAF 51/261 reads (20%) | called by muse, mutect2, varscan2
- FSHR | c.1923G>T p.L641= | Silent (SNP) | VAF 156/1049 reads (15%) | called by muse, mutect2, varscan2
- GFRA2 | c.651C>T p.Y217= | Silent (SNP) | VAF 56/427 reads (13%) | called by muse, mutect2, varscan2
- H4C11 | c.228C>T p.H76= | Silent (SNP) | VAF 25/232 reads (11%) | catalogued as rs578165187; called by muse, mutect2, varscan2
- HERC1 | c.12360C>T p.D4120= | Silent (SNP) | VAF 56/360 reads (16%) | called by muse, mutect2, varscan2
- HMCN1 | c.14250C>T p.N4750= | Silent (SNP) | VAF 93/1106 reads (8%) | called by muse, mutect2
- HTR3B | c.162C>A p.T54= | Silent (SNP) | VAF 41/274 reads (15%) | catalogued as COSV52744598; called by muse, mutect2, varscan2
- KCNB1 | c.733C>T p.L245= | Silent (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- KIAA0232 | c.2955G>T p.G985= | Silent (SNP) | VAF 71/478 reads (15%) | catalogued as COSV56929936; called by muse, mutect2, varscan2
- KRT31 | c.1221C>A p.R407= | Silent (SNP) | VAF 37/244 reads (15%) | called by muse, mutect2, varscan2
- KRT9 | c.1278C>A p.V426= | Silent (SNP) | VAF 71/520 reads (14%) | catalogued as rs1426969303; called by muse, mutect2, varscan2
- LAMA2 | c.6480A>G p.P2160= | Silent (SNP) | VAF 52/540 reads (10%) | called by muse, mutect2
- LGI4 | c.291G>C p.A97= | Silent (SNP) | VAF 23/244 reads (9%) | catalogued as rs766169320; called by muse, mutect2
- LHX6 | c.681C>T p.T227= (on ENST00000373755 / NM_001242334.2; = p.T256= on NM_014368.5) | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as COSV61345837; called by muse, mutect2, varscan2
- LRRTM4 | c.1614C>T p.C538= | Silent (SNP) | VAF 86/647 reads (13%) | catalogued as COSV69162753; called by muse, mutect2, varscan2
- MATK | c.114C>G p.V38= (on ENST00000310132 / NM_139355.3; = p.V39= on NM_002378.4) | Silent (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2
- MPHOSPH9 | c.1038C>G p.L346= | Silent (SNP) | VAF 20/378 reads (5%) | called by muse, mutect2
- MPO | c.951G>T p.P317= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as COSV56566483, COSV99832871; called by muse, mutect2, varscan2
- MTR | c.3499C>A p.R1167= | Silent (SNP) | VAF 95/356 reads (27%) | catalogued as rs751671789; called by muse, mutect2, varscan2
- MUC16 | c.5382C>T p.T1794= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs773887288; called by muse, mutect2
- MUC5B | c.5313C>A p.P1771= | Silent (SNP) | VAF 49/247 reads (20%) | catalogued as COSV71593925; called by muse, mutect2, varscan2
- MYOD1 | c.366G>A p.L122= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV51454171; called by muse, mutect2, varscan2
- OOSP2 | c.159G>T p.L53= | Silent (SNP) | VAF 19/260 reads (7%) | called by muse, mutect2
- OR13A1 | c.630C>A p.T210= | Silent (SNP) | VAF 32/219 reads (15%) | called by muse, mutect2, varscan2
- OR2T1 | c.942A>T p.S314= | Silent (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- OR6C75 | c.621C>G p.V207= | Silent (SNP) | VAF 37/581 reads (6%) | called by muse, mutect2
- OTOGL | c.2860C>A p.R954= (on ENST00000547103; = p.R945= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/408 reads (7%) | catalogued as COSV72006450; called by muse, mutect2
- PAQR5 | c.723C>T p.R241= | Silent (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- PDE4A | c.1989A>T p.P663= (on ENST00000380702 / NM_001111307.2; = p.P424= on NM_006202.3) | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- PEX6 | c.39G>T p.P13= | Silent (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- PLD5 | c.570A>T p.T190= (on ENST00000442594; = p.T128= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/259 reads (20%) | called by muse, mutect2, varscan2
- PLEC | c.13068G>T p.L4356= (on ENST00000322810 / NM_201380.4; = p.L4246= on NM_000445.5) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs1554671259; called by muse, mutect2, varscan2
- PURG | c.315G>T p.L105= | Silent (SNP) | VAF 43/337 reads (13%) | catalogued as COSV53306439; called by muse, mutect2, varscan2
- RTN1 | c.2262G>A p.R754= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as rs1165145887; called by muse, mutect2, varscan2
- RWDD1 | c.6A>T p.T2= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as COSV63972723; called by muse, mutect2, varscan2
- SERPINB10 | c.750G>T p.L250= | Silent (SNP) | VAF 27/481 reads (6%) | catalogued as COSV53072665; called by muse, mutect2
- SETD1B | c.2856G>A p.G952= | Silent (SNP) | VAF 27/285 reads (9%) | called by muse, mutect2
- SHROOM3 | c.1233G>T p.R411= | Silent (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- SIRPB1 | c.144G>A p.E48= | Silent (SNP) | VAF 52/394 reads (13%) | called by muse, mutect2, varscan2
- SLC8A3 | c.2517C>T p.A839= (on ENST00000381269 / NM_183002.3; = p.A837= on NM_033262.4) | Silent (SNP) | VAF 36/248 reads (15%) | called by muse, mutect2, varscan2
- SOX30 | c.522C>A p.A174= | Silent (SNP) | VAF 33/273 reads (12%) | called by muse, mutect2, varscan2
- UGT2B4 | c.450A>T p.A150= | Silent (SNP) | VAF 35/400 reads (9%) | catalogued as COSV100522222; called by muse, mutect2
- UNC79 | c.909C>G p.P303= (on ENST00000393151 / NM_001346218.2; = p.P126= on NM_020818.5) | Silent (SNP) | VAF 30/302 reads (10%) | called by muse, mutect2
- VPS13B | c.7131T>C p.P2377= | Silent (SNP) | VAF 23/290 reads (8%) | called by muse, mutect2
- WDR87 | c.5604C>A p.T1868= | Silent (SNP) | VAF 30/209 reads (14%) | called by muse, mutect2, varscan2
- ZEB2 | c.1899C>A p.A633= | Silent (SNP) | VAF 78/619 reads (13%) | catalogued as COSV57961292; called by muse, mutect2, varscan2
- ZNF548 | c.1056C>G p.L352= | Silent (SNP) | VAF 28/189 reads (15%) | called by muse, mutect2, varscan2
- ZNF648 | c.807G>A p.A269= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as rs1415448211, COSV100374565; called by muse, mutect2, varscan2
- AC107023.1 | n.25+739A>T | Intron (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- AC136759.1 | n.1129C>T | RNA (SNP) | VAF 69/562 reads (12%) | called by muse, mutect2, varscan2
- ACE | c.2642-9C>A | Intron (SNP) | VAF 23/294 reads (8%) | called by muse, mutect2
- ASCC1 | c.*248G>T | 3'UTR (SNP) | VAF 74/463 reads (16%) | called by mutect2, varscan2
- ATP4A | c.*35del | 3'UTR (DEL) | VAF 14/123 reads (11%) | called by pindel, varscan2
- C7orf65 | n.447T>A | RNA (SNP) | VAF 28/174 reads (16%) | called by muse, varscan2
- C8orf87 | n.321del | RNA (DEL) | VAF 87/736 reads (12%) | called by mutect2, pindel, varscan2
- CHMP2B | c.425-12C>T | Intron (SNP) | VAF 28/409 reads (7%) | catalogued as rs749814652; called by muse, mutect2
- CLN3 | c.834+43G>C | Intron (SNP) | VAF 53/313 reads (17%) | called by muse, mutect2, varscan2
- CSMD3 | c.7885+85C>A | Intron (SNP) | VAF 22/311 reads (7%) | called by muse, mutect2
- DCAF8 | c.723+88_723+91del | Intron (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- DYSF | c.*20A>G | 3'UTR (SNP) | VAF 45/350 reads (13%) | called by muse, mutect2, varscan2
- EIF3H | c.290-30101_290-30100insT | Intron (INS) | VAF 13/103 reads (13%) | called by mutect2, pindel*
- EPB41L3 | c.2350-2426A>T | Intron (SNP) | VAF 21/365 reads (6%) | called by muse, mutect2
- ERAP1 | c.1943+45T>A | Intron (SNP) | VAF 58/359 reads (16%) | called by muse, mutect2, varscan2
- FBXO4 | c.-9G>C | 5'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- FOXN2 | c.1del | 5'UTR (DEL) | VAF 18/124 reads (15%) | called by pindel, varscan2
- GSE1 | c.2464+1716C>A | Intron (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- GTF3C6 | c.-5G>T | 5'UTR (SNP) | VAF 38/291 reads (13%) | called by muse, mutect2, varscan2
- HPS5 | c.*25A>G | 3'UTR (SNP) | VAF 18/498 reads (4%) | catalogued as rs1329193985; called by muse, mutect2
- LILRA2 | c.1255+1492G>T | Intron (SNP) | VAF 11/226 reads (5%) | called by muse, mutect2
- MIR205 | chr1:209429303 C>A | 5'Flank (SNP) | VAF 18/217 reads (8%) | catalogued as rs781078620; called by muse, mutect2
- MIR510 | n.3G>A | RNA (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- MTHFD2L | chr4:74157969 C>T | 5'Flank (SNP) | VAF 27/287 reads (9%) | called by muse, mutect2
- NBPF11 | c.-548-2929G>T | Intron (SNP) | VAF 112/446 reads (25%) | called by muse, mutect2, varscan2
- NOP10 | c.-22G>T | 5'UTR (SNP) | VAF 53/390 reads (14%) | called by muse, mutect2, varscan2
- NOP56 | c.569+143C>T | Intron (SNP) | VAF 9/174 reads (5%) | called by muse, mutect2
- OR51A4 | chr11:4943445 G>T | 3'Flank (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- OR6W1P | n.473C>T | RNA (SNP) | VAF 34/264 reads (13%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.1641+158C>A | Intron (SNP) | VAF 13/136 reads (10%) | catalogued as COSV52995212; called by muse, mutect2
- PHACTR2 | c.-28A>G | 5'UTR (SNP) | VAF 84/513 reads (16%) | catalogued as rs1310299830; called by muse, mutect2, varscan2
- PPP2CB | chr8:30812843 G>C | 5'Flank (SNP) | VAF 41/235 reads (17%) | called by muse, mutect2, varscan2
- RALYL | c.-24+557C>A | Intron (SNP) | VAF 74/542 reads (14%) | catalogued as COSV101569081; called by muse, mutect2, varscan2
- SIX1 | c.-29T>A | 5'UTR (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- SLIT2 | c.*1354G>T | 3'UTR (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- SNTG1 | c.1039-13A>C | Intron (SNP) | VAF 79/705 reads (11%) | called by muse, mutect2, varscan2
- SOX2 | c.-18C>T | 5'UTR (SNP) | VAF 6/51 reads (12%) | catalogued as rs1444210633; called by muse, mutect2
- SPATA33 | chr16:89657783 T>A | 5'Flank (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- SWI5 | c.-1G>T | 5'UTR (SNP) | VAF 34/244 reads (14%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*2782T>C | 3'UTR (SNP) | VAF 69/525 reads (13%) | called by muse, mutect2, varscan2
- TSC22D4 | c.930-429G>T | Intron (SNP) | VAF 7/51 reads (14%) | catalogued as rs1251379811, COSV55725594; called by muse, mutect2
- TUBB7P | n.334C>A | RNA (SNP) | VAF 71/515 reads (14%) | called by muse, mutect2, varscan2
- USH1C | c.*17C>A | 3'UTR (SNP) | VAF 62/438 reads (14%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438031 C>T | 5'Flank (SNP) | VAF 27/147 reads (18%) | catalogued as rs1039479066; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2096+11T>G | Intron (SNP) | VAF 73/570 reads (13%) | called by muse, mutect2, varscan2
- ZNF99 | c.*124G>T | 3'UTR (SNP) | VAF 26/284 reads (9%) | catalogued as COSV68057131; called by muse, mutect2
